Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A0JE, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A0JE-01A (Primary Tumor).

[page 1 of 5]
Clinical Diagnosis & History:

year old female with right breast cancer diagnosed on core biopsy.

Specimens Submitted:

- 1: SP: Sentinel node #1, level 1, right axilla
- 2: SP: Sentinel node #2, level 1, right axilla (fs)
- 3: SP: Right breast mass
- 4: SP: Additional medial margin
- 5: SP: Superior lateral tissue, right breast
- 6: SP: Level 1 and 2, right axillary contents with tags attached

DIAGNOSIS:

- 1) SENTINEL NODE #1, LEVEL I, RIGHT AXILLA; EXCISION:
- METASTATIC CARCINOMA INVOLVING ONE LYMPH NODE (1/1).
- NO EXTRANODAL EXTENSION IS IDENTIFIED.
- 2) SENTINEL NODE #2, LEVEL I, RIGHT AXILLA; EXCISION:
- METASTATIC CARCINOMA INVOLVING ONE LYMPH NODE (1/1).
- EXTRANODAL EXTENSION IS IDENTIFIED AND MEASURES 0.5 CM.
- 3) BREAST, MASS, RIGHT; EXCISION:
- INVASIVE DUCTAL CARCINOMA, NOS TYPE, HISTOLOGIC GRADE III/III (SLIGHT OR NO TUBULE FORMATION), NUCLEAR GRADE III/III (MARKED VARIATION IN SIZE AND SHAPE), MEASURING 2.5 CM IN LARGEST DIMENSION MICROSCOPICALLY.
- DUCTAL CARCINOMA IN SITU (DCIS) IS ALSO IDENTIFIED, SOLID TYPE, WITH HIGH NUCLEAR GRADE AND EXTENSIVE NECROSIS.
- LOBULAR INVOLVEMENT BY DCIS IS PRESENT.
- THE DCIS CONSTITUTES <25% OF THE TOTAL TUMOR MASS, AND IS PRESENT ADMIXED WITH AND AWAY FROM THE INVASIVE COMPONENT.
- CALCIFICATIONS ARE PRESENT IN THE IN SITU, AND IN BENIGN BREAST PARENCHYMA.
- NO VASCULAR INVASION IS NOTED.
- A MICROSCOPIC FOCUS OF INVASIVE CARCINOMA (<1 MM) IS PRESENT IN ONE OUT OF SIX SECTIONS OF THE ANTERIOR SHAVED MARGIN.
- DCIS INVOLVES THE FOLLOWING SHAVED MARGINS: SUPERIOR (ONE OUT OF FOUR SLIDES), INFERIOR (ONE OUT OF SIX SLIDES) AND POSTERIOR (TWO OUT OF FIVE

** Continued on next page **

ICD-0-3

carcinoma, infiltrating duct, nos 8500/3
Site: breast, nos C50.9 w 10/22/11

[page 2 of 5]
SLIDES).

Page 2 of 5

- THE NON-NEOPLASTIC BREAST TISSUE SHOWS BIOPSY SITE CHANGES, FIBROCYSTIC CHANGES, AND USUAL DUCTAL HYPERPLASIA.
- RECEPTOR STUDIES WERE PERFORMED ON PRIOR MATERIAL (CORE BIOPSY,

- 4) BREAST, RIGHT, ADDITIONAL MEDIAL MARGIN; EXCISION:
- BENIGN BREAST TISSUE WITH DUCTAL HYPERPLASIA WITHOUT ATYPIA.
- 5) BREAST, RIGHT, SUPEROLATERAL TISSUE; EXCISION:
- FOCAL ATYPICAL DUCTAL HYPERPLASIA.
- 6) LYMPH NODES, LEVELS I AND II, RIGHT AXILLARY CONTENTS; DISSECTION:
- LEVEL I: EIGHT BENIGN LYMPH NODES (0/8).
- LEVEL II: SIX OF NINETEEN LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA (6/19).
- EXTRANODAL EXTENSION IS IDENTIFIED (2 MM).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description.

2

1) The specimen is received initially fresh for frozen section consultation, which was later canceled, labeled, "Sentinel node number one, level 1, right axilla", and consists of a single lymph node measuring 1.8 x 1.2 x 0.6 cm. Cut section shows fleshy red-tan appearance. Specimen is entirely submitted.

Summary of sections:

U bisected lymph node

2). The specimen is received fresh for frozen section consultation labeled, "Sentinel node number two, level 1, right axilla", and consists of a single lymph node measuring 1.2 x 0.7 x 0.4 cm. The specimen is bisected and entirely frozen. A sample is submitted to TPS.

Summary of sections:

** Continued on next page **

[page 3 of 5]
3) The specimen is received fresh, labeled "Right breast mass". It consists of a round piece of fibroadipose tissue measuring 11.5 x 10.0 x 4.0 cm. The specimen is oriented with short suture superior and long suture lateral. The specimen is inked and the margins are entirely shaved. Sectioning of the central portion of the tissue reveals a firm stellate shaped gray-tan mass measuring 2.0 x 2.0 x 1.5 cm located at the lateral aspect of the tissue. A portion of the tissue is submitted for TPS. The rest of the tumor is entirely submitted for histologic examination. Representative section of the remaining tissue are also submitted.

Summary of Sections:

S superior margin
I inferior margin
M medial margin
L lateral margin
A anterior margin
P posterior margin
T tumor
R representative section of remaining tissue

4) The specimen is received fresh, labeled "Additional medial margin, stitch marks final margin breast". It consists of a fragment of fibroadipose tissue measuring 4.0 x 2.0 x 0.4 cm. The surface of the tissue marked with stitch is inked black. The tissue is serially sectioned to reveal a fibroadipose cut surface with no gross pathologic abnormality. The specimen is entirely submitted.

Summary of Sections:

U - undesignated

5) The specimen is received fresh, labeled "Superior lateral tissue, right breast". It consists of a round piece of fibroadipose tissue measuring 3.0 x 2.0 x 0.5 cm. The surface of the tissue marked with stitch is inked black and the tissue is serially sectioned to reveal a fibroadipose cut surface with no gross pathologic abnormalities. The specimen is entirely submitted.

Summary of Sections:

U - undesignated

6) The specimen is received fresh, labeled "Levels 1 and 2, right axillary contents, with tags attached". It consists of a fragment of adipose tissue measuring 7 x 4 x 3 cm with attached tags designating levels 1 and 2. Dissection of tissue reveals multiple lymph nodes ranging in size from 0.2 x 0.2 x 0.1 cm to 1.2 x 1.0 x 0.5 cm. All lymph nodes are entirely

** Continued on next page **

[page 4 of 5]
submitted.

Page 4 of 5

Summary of Sections:

LN1 - Lymph nodes, level 1
LN2 - Lymph nodes, level 2

6. SP: Level 1 and 2, right axillary contents with tags attached (am):

Summary of Sections:

Part 1: SP: Sentinel node #1, level 1, right axilla

Block	Sect.	Site	PCs
1		u	1

Part 2: SP: Sentinel node #2, level 1, right axilla (fs)

Block	Sect.	Site	PCs
1		fsc	1

Part 3: SP: Right breast mass

Block	Sect.	Site	PCs
6		A	6
6		I	6
2		L	26
1		M	1
5		P	5
1		R	1
4		S	4
4		T	4

4

Part 4: SP: Additional medial margin

Block	Sect.	Site	PCs
3		u	3

Part 5: SP: Superior lateral tissue, right breast

Block	Sect.	Site	PCs
3		u	3

Part 6: SP: Level 1 and 2, right axillary contents with tags attached

Block	Sect.	Site	PCs
4		LN1	8
5		LN2	10

Intraoperative Consultation:

** Continued on next page **

[page 5 of 5]
----- Page 5 of 5
Note: The diagnoses given in this section pertain only to the
tissue sample examined at the time of the intraoperative
consultation.

- 2) FROZEN SECTION DIAGNOSIS: POSITIVE FOR CARCINOMA.
PERMANENT DIAGNOSIS: SAME.

AD

S

** End of Report **

Source: NCI Genomic Data Commons file de1be4f3-c0f0-47fb-8272-d7d98aa52ae2 (TCGA-AO-A0JE.15CAD156-1E40-4C83-B3ED-484964FE407F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).